Surgical pathology report (de-identified scan), TCGA case TCGA-24-1930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1930-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-1930

Final Dx: OVARY, LEFT, OOPHORECTOMY
- ADENOCARCINOMA, PAPILLARY SEROUS TYPE (SEE MICROSCOPIC COMMENT)

OVARY, RIGHT, OOPHORECTOMY
- ADENOCARCINOMA, PAPILLARY SEROUS TYPE

OMENTUM, OMENTECTOMY
- METASTATIC ADENOCARCINOMA

LYMPH NODE, RIGHT ILIAC, EXCISION
- METASTATIC ADENOCARCINOMA (1/1)

LYMPH NODE, LEFT PARA-AORTIC, EXCISION
- METASTATIC ADENOCARCINOMA (1/1)

Primary Path:

Resident Path:

Frozen Sect:

FS: Left ovary, neoplasm, oophorectomy - "Poorly-differentiated
adenocarcinoma of mullerian
origin," by

Gross: The specimens are received in six formalin-filled containers labeled with the patient's name. The first container is additionally labeled "FS" and contains a single irregularly-shaped fragment of nodular tan-white soft tissue measuring 2.8 x 2.0 x 0.2 cm in greatest dimension.

The second container is additionally labeled "X - left tube and ovary" and contains a previously serially sectioned ovary which, upon reconstruction, conforms to the above stated dimensions. The ovarian surface is gray-white, lobulated and there is gross evidence of tumor on the surface of the ovary. On cut surface, tumor is tan and multilobulated with intervening fibrous strands. Densely adherent to the ovarian tumor is a 5.0 cm long x 0.1 cm densely hemorrhagic and fibrous structure which is grossly consistent with fallopian tube. Labeled XA through XG - sections of ovarian tumor; Xh - section of possible fallopian tube.

The third container is additionally labeled "omentum" and contains a 25 x 19 x 4 cm irregularly-shaped fragment of firm, nodular tan-white tissue, grossly consistent with omentum. The tissue is diffusely and extensively involved by pink-tan tumor. Labeled A1 and

[page 2 of 4]
[REDACTED]

The fourth container is additionally labeled "right ovary" and contains numerous pink-white, friable tumor fragments measuring 10 x 7 x 4 cm. The largest fragment measures 7 x 5 x 5 cm and

appears to represent an ovary involved by tumor. The serosal surface is irregularly nodular suggesting tumor involvement. No fallopian tube can be grossly identified on the surface of the specimen. The largest fragment is serially sectioned to show lobulated, partially necrotic tan-white tumor, diffusely involving the entire fragment. Despite extensive sectioning, a fallopian tube is not identified. Labeled B1 through B6. Jar 2.

The fifth container is additionally labeled "para-aortic lymph node" and contains a single irregularly-shaped fragment of fibroadipose tissue measuring 1.3 x 0.8 x 0.4 cm in aggregate. It is submitted in toto. [REDACTED]

The sixth container is additionally labeled "right iliac lymph node" and contains a lymph node measuring 2.5 x 1.5 x 0.4 cm in maximum dimension. It is submitted in toto. Labeled D. Jar 0. [REDACTED]

Comment: Sections of both the left and right ovaries show a poorly differentiated adenocarcinoma, most consistent with papillary serous adenocarcinoma. The surfaces of both ovaries are involved. There is also diffuse omental involvement by tumor. Both the right iliac and para-aortic lymph nodes show involvement by metastatic adenocarcinoma. Sections of the adnexal structure attached to the left ovary which were submitted as possible right fallopian tube showed diffuse involvement by adenocarcinoma. Whether this represents replacement of the fallopian tube epithelium by tumor, or simply tumor present on the ovarian surface in the absence of the left fallopian tube, cannot be determined. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT. 2. The HISTOLOGIC DIAGNOSIS is:

Serous adenocarcinoma

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:

Right and left ovary (synchronous primary tumors)

4. The FIGO GRADE of the tumor is:

III (Tumor composed of greater than 50% solid cellular nests)

5. The NUCLEAR (BRODERS') GRADE of the tumor is:

G3 (Poorly-differentiated)

6. Tumor IS identified on the ovarian surface of both ovaries.

7. The presence of tumor invasion of the mesovarium CANNOT BE EVALUATED.

8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED.

9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.

10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.

11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.

12. Metastatic involvement of the omentum is PRESENT.

13. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.

[page 3 of 4]
TCGA-24-1930

14. Metastatic involvement of the endometrium CANNOT BE EVALUATED.

15. Regional lymph node metastases are PRESENT.

16. The total number of regional lymph nodes examined is 2

17. The total number of metastatically-involved regional lymph nodes is 2.

Extranodal extension by tumor metastases is ABSENT

18. DETAILED STAGING INFORMATION: Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as:

N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

19. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History: The patient is a [REDACTED] with a left ovarian mass. Operative procedure: Left salpingo-oophorectomy and omentectomy.

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pickup left ovary and tube consisting of 8.5 x 7 x 4.0 cm adnexa which is tan-yellow, multilobulated and nodular with irregular surface. The cut surface shows intervening soft, fibrous strands. Section frozen as FS is small cystic area containing clear, serous fluid. The fallopian tube is 5.0 cm long and 1.0 cm in maximum diameter. It is serially sectioned to show that it is grossly unremarkable," [REDACTED]

Source: NCI Genomic Data Commons file b0f54e0f-0383-47f6-bad1-5bd02352cb8b (TCGA-24-1930.746AC85A-EA6D-4D60-859F-69BF580A707C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).